Somatic mutation profile of tumor specimen TCGA-EE-A2MP-06A (aliquot TCGA-EE-A2MP-06A-11D-A197-08) from TCGA case TCGA-EE-A2MP, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 52.6 years (19,216 days).
Specimen TCGA-EE-A2MP-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20ee083b-c78a-408f-8014-9ac506c2a474.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MP-10A (Blood Derived Normal), aliquot TCGA-EE-A2MP-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c551b9f-bdcf-4511-bf6d-9981f8a1e34e

The open-access MAF lists 347 somatic variants for this specimen: 242 protein-altering or splice-affecting, 95 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 214, Silent 95, Nonsense Mutation 13, Intron 5, Splice Site 4, Frame Shift Del 4, RNA 3, Frame Shift Ins 2, In Frame Del 2, Translation Start Site 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CFTR | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs121909017, CM920156, COSV50068549; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556407064, CM145036, COSV60365226; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KNSTRN | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 20/45 reads (44%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.998); catalogued as COSV51106838; called by muse, mutect2, varscan2
- RPS6KA4 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV53700569; called by muse, mutect2, varscan2
- AAMP | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866477359, COSV50308258, COSV50308704; called by muse, mutect2, varscan2
- ACTL7B | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1301600694, COSV65926925; called by muse, mutect2, varscan2
- ALPK3 | c.3125G>A p.G1042D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV51935580; called by mutect2, varscan2
- ANO10 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.158); catalogued as COSV52730752, COSV52733131; called by muse, mutect2, varscan2
- AP4M1 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100384609, COSV57997351; called by muse, mutect2, varscan2
- APOB | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 150/337 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.385); catalogued as COSV51942031; called by muse, mutect2, varscan2
- ARF4 | c.154A>G p.N52D | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV57715342; called by muse, mutect2, varscan2
- ATP8A1 | c.1040T>A p.F347Y | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.914); catalogued as COSV52539630; called by muse, mutect2, varscan2
- B3GALNT2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs545999890, COSV64003575; called by muse, mutect2, varscan2
- BCL6 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV51651683; called by muse, mutect2, varscan2
- BCS1L | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.101); catalogued as COSV55308314; called by muse, mutect2, varscan2
- BMX | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 111/255 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV59592086; called by muse, mutect2, varscan2
- BPIFB2 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs761917219, COSV50066618; called by muse, mutect2, varscan2
- BRCA2 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66456892; called by muse, varscan2
- BRINP3 | c.1422C>A p.C474* | Nonsense Mutation (SNP) | VAF 27/192 reads (14%) | catalogued as COSV66529923; called by muse, mutect2, varscan2
- BTBD11 | c.2575G>A p.E859K (on ENST00000280758 / NM_001018072.2; = p.E396K on NM_001017523.2) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as rs1339741639, COSV55028361, COSV55033021; called by muse, mutect2, varscan2
- C11orf16 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs775467820, COSV55148760, COSV55149544; called by muse, mutect2, varscan2
- CACNA2D3 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs772601031, COSV55554973; called by muse, mutect2, varscan2
- CCDC102B | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); catalogued as COSV60144441; called by muse, mutect2, varscan2
- CD2 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV65644387; called by muse, mutect2, varscan2
- CDCA8 | c.489-1G>A p.X163_splice | Splice Site (SNP) | VAF 72/155 reads (46%) | catalogued as rs759570876, COSV59239455; called by muse, mutect2, varscan2
- CDH17 | c.1695A>C p.Q565H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.251); catalogued as COSV50331998; called by mutect2, varscan2
- CDH8 | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.967); catalogued as COSV54879075; called by muse, mutect2, varscan2
- CDH9 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV50325969, COSV50406227; called by muse, mutect2, varscan2
- CDH9 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as rs868604878, COSV50254395, COSV50326277; called by muse, mutect2, varscan2
- CDKAL1 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV51185785; called by muse, mutect2, varscan2
- CDR1 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 76/251 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV65164450; called by muse, mutect2, varscan2
- CDX4 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV65171733; called by muse, mutect2, varscan2
- CFAP221 | c.1222-1G>A p.X408_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as COSV54659334; called by muse, mutect2, varscan2
- CHAC2 | c.70T>A p.Y24N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV54858235; called by muse, mutect2, varscan2
- CHD7 | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1384228127, COSV71112437; called by muse, mutect2
- CHRNA3 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58775002, COSV58776138; called by muse, mutect2, varscan2
- CLCA4 | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65284142; called by muse, mutect2, varscan2
- CLEC4C | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 37/83 reads (45%) | catalogued as COSV63582865; called by muse, mutect2, varscan2
- CLSTN2 | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs201002193, COSV71722089; called by muse, mutect2, varscan2
- CNTNAP2 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.135); catalogued as COSV62211006; called by muse, mutect2, varscan2
- CYP4A22 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV53741056; called by muse, mutect2, varscan2
- CYP4F2 | c.1264A>G p.I422V | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as COSV55619445; called by muse, mutect2, varscan2
- DAB2 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV100298138, COSV57912997, COSV57916154; called by muse, mutect2, varscan2
- DEFB118 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV53620718, COSV99489301; called by muse, mutect2, varscan2
- DENND2A | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV52054056; called by muse, mutect2, varscan2
- DGAT2L6 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.796); catalogued as COSV100284018; called by muse, mutect2, varscan2
- DHX37 | c.2579-1G>A p.X860_splice | Splice Site (SNP) | VAF 8/15 reads (53%) | catalogued as COSV58136437; called by muse, mutect2, varscan2
- DNAH2 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66721933; called by muse, mutect2, varscan2
- DNAH2 | c.9400C>T p.R3134* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV66718052; called by muse, mutect2, varscan2
- DNAH5 | c.10654G>A p.A3552T | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV54216451; called by muse, mutect2, varscan2
- DNAH9 | c.6437C>T p.S2146F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52358747; called by muse, mutect2, varscan2
- DNHD1 | c.1696C>T p.H566Y | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54438819; called by muse, mutect2, varscan2
- DOP1B | c.5041G>A p.A1681T | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV67694105; called by muse, mutect2, varscan2
- DRAM2 | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV54415887; called by muse, mutect2, varscan2
- DRP2 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.969); catalogued as COSV65810880; called by muse, mutect2, varscan2
- DSP | c.2637G>A p.W879* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV65793799; called by muse, mutect2, varscan2
- DUSP4 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.293); catalogued as rs772256235, COSV53545403; called by muse, varscan2
- DUXA | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV73729774; called by muse, mutect2, varscan2
- DYNC1LI2 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99263062; called by muse, mutect2, varscan2
- EMD | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.354); catalogued as COSV63962310; called by muse, mutect2, varscan2
- EMSY | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58263000; called by muse, mutect2, varscan2
- EOMES | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1282463689, COSV99841899; called by muse, mutect2
- ERAP2 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV65940292; called by muse, mutect2, varscan2
- F13A1 | c.2144T>C p.L715P | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53561691; called by muse, mutect2, varscan2
- FBXL7 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV61648520; called by muse, mutect2, varscan2
- FBXO21 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57973727; called by muse, mutect2, varscan2
- FBXO9 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1002583521, COSV55056328; called by muse, mutect2, varscan2
- FCRL5 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0.029); catalogued as COSV62516638; called by muse, mutect2, varscan2
- FGD5 | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs376683524; called by muse, mutect2, varscan2
- FILIP1L | c.1307A>G p.K436R (on ENST00000354552 / NM_182909.3; = p.K196R on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.158); catalogued as COSV58771588; called by muse, mutect2, varscan2
- FLRT3 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV54009673; called by muse, mutect2, varscan2
- FLT1 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757138085, COSV56727084; called by muse, varscan2
- FLT1 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99162481; called by muse, varscan2
- FLT3 | c.2809C>T p.P937S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758146765, COSV99609015; called by muse, mutect2, varscan2
- FSTL5 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs773979170, COSV60180450; called by muse, mutect2, varscan2
- FYN | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV99991910; called by muse, mutect2, varscan2
- FYN | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV99991913; called by muse, mutect2, varscan2
- GAL3ST1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs148732637; called by muse, varscan2
- GLIS1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760422919, COSV56551516, COSV56555273; called by mutect2, varscan2
- GMPPA | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV58008918; called by muse, mutect2, varscan2
- GNL3 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs375232066; called by muse, mutect2, varscan2
- GNL3 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs761275727, COSV99803874; called by muse, mutect2, varscan2
- GRB7 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV58449004; called by muse, mutect2, varscan2
- GRIA3 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs867194096, COSV52068926; called by muse, mutect2, varscan2
- HAPLN1 | c.170T>A p.V57D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99164985; called by muse, mutect2, varscan2
- HAPLN1 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as rs1176315629, COSV57149537; called by muse, mutect2, varscan2
- HGF | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); catalogued as COSV55946053, COSV55949960; called by muse, mutect2, varscan2
- HIVEP1 | c.6521G>A p.G2174E | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65103056; called by muse, mutect2, varscan2
- HLA-DQA1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV58240173; called by muse, mutect2, varscan2
- HMG20A | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV60313234; called by muse, mutect2, varscan2
- IFNA16 | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1296599230, COSV66510350; called by muse, mutect2, varscan2
- IGHV4-31 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.528); catalogued as rs767450644; called by muse, mutect2, varscan2
- IL17D | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as rs772734326, COSV59231628; called by muse, mutect2, varscan2
- IL31RA | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV51682830; called by muse, mutect2, varscan2
- IL3RA | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV58432146; called by muse, mutect2, varscan2
- INPP5J | c.1464G>A p.M488I (on ENST00000331075 / NM_001284285.2; = p.M120I on NM_001002837.2) | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV58513865; called by muse, mutect2, varscan2
- INTS1 | c.4754C>T p.S1585F | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV67178244; called by muse, mutect2, varscan2
- IPO5 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1211038216, COSV55156138; called by muse, mutect2, varscan2
- IPP | c.1384T>C p.S462P | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV63433043; called by muse, mutect2, varscan2
- ITGB3 | c.323A>G p.Q108R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71384467; called by muse, mutect2, varscan2
- JCAD | c.3713A>G p.K1238R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.33); catalogued as COSV64760509; called by muse, mutect2, varscan2
- KCNK13 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56414507; called by muse, mutect2, varscan2
- KCNQ5 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.588); catalogued as COSV59668601; called by muse, mutect2, varscan2
- KCTD3 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52068212; called by muse, mutect2, varscan2
- KDM3B | c.4402A>T p.I1468F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV58692485; called by muse, mutect2, varscan2
- KIAA0513 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs867351382, COSV50742281; called by muse, mutect2, varscan2
- KIF1A | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100241294; called by muse, mutect2, varscan2
- KRT19 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1343205127, COSV54180338; called by muse, mutect2, varscan2
- LAMB4 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV52717302, COSV52723351; called by muse, mutect2, varscan2
- LARP4 | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53320727; called by muse, mutect2, varscan2
- LELP1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); catalogued as rs761668608, COSV64202571; called by muse, mutect2, varscan2
- LILRA1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs141328341; called by muse, mutect2, varscan2
- LMNTD1 | c.725C>G p.P242R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51448464; called by muse, mutect2, varscan2
- LPP | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs1440811918, COSV57099709; called by muse, mutect2
- LRRC31 | c.1433G>C p.R478P | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52981563, COSV52982312; called by muse, mutect2, varscan2
- LRRC7 | c.238T>A p.F80I (on ENST00000651989 / NM_001370785.2; = p.F47I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50500783; called by mutect2, varscan2
- LRRIQ4 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV61619588; called by muse, mutect2, varscan2
- MAP3K2 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV100789339; called by muse, mutect2, varscan2
- MAPKBP1 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as rs200340654, COSV52963952; called by muse, mutect2, varscan2
- MAS1L | c.842G>A p.S281N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV65809165; called by muse, mutect2, varscan2
- MFSD14A | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 32/94 reads (34%) | catalogued as COSV54928720; called by muse, mutect2, varscan2
- MUC16 | c.26870C>T p.P8957L | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as rs1316682536, COSV67477140; called by muse, mutect2, varscan2
- MUC3A | c.8192C>T p.P2731L | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as rs1393924834, COSV60219255; called by muse, mutect2
- MYH2 | c.4072G>A p.E1358K | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1263474588, COSV55441802; called by muse, varscan2
- MYOM1 | c.3226G>A p.D1076N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs980739302, COSV55295113, COSV55296048; called by muse, mutect2, varscan2
- NBEAL2 | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.96); catalogued as COSV52760303; called by muse, mutect2
- NCAPH2 | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV52688497, COSV99329289; called by muse, mutect2, varscan2
- NEDD4L | c.1735C>T p.P579S (on ENST00000400345 / NM_001144967.3; = p.P559S on NM_015277.6) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99895179; called by muse, mutect2, varscan2
- NELFB | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as COSV100546920; called by muse, mutect2, varscan2
- NID2 | c.2383G>A p.D795N | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53498998; called by muse, mutect2, varscan2
- NIPAL1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV55006511; called by muse, mutect2, varscan2
- NKG7 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs763759820, COSV52468469; called by muse, mutect2, varscan2
- NOD2 | c.976C>T p.L326F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV56049149, COSV56052515; called by muse, mutect2, varscan2
- NOTCH4 | c.3269C>T p.S1090F | Missense Mutation (SNP) | VAF 112/231 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs750694083, COSV66681952; called by muse, mutect2, varscan2
- NPAS4 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs953694683, COSV60651331, COSV60651779; called by muse, mutect2, varscan2
- NPSR1 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV62196056; called by muse, mutect2, varscan2
- NRXN1 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58463010; called by muse, mutect2, varscan2
- NT5C1B | c.441C>T p.L147= (on ENST00000359846 / NM_001199086.2; = p.L87= on NM_033253.4) | Splice Region (SNP) | VAF 4/21 reads (19%) | catalogued as COSV58397178; called by muse, mutect2
- NUDT10 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100726827; called by muse, mutect2, varscan2
- OLFML2B | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.263); catalogued as COSV54197782; called by muse, mutect2, varscan2
- OR13C4 | c.887A>T p.Y296F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52927428; called by muse, mutect2, varscan2
- OR14A16 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as COSV62926952; called by muse, mutect2, varscan2
- OR1L8 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV59186972; called by muse, mutect2, varscan2
- OR4C11 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56353176; called by muse, mutect2, varscan2
- OR4C15 | c.748C>T p.L250F (on ENST00000314644; = p.L196F on NM_001001920.2) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.105); catalogued as COSV58953808; called by muse, mutect2, varscan2
- OR4C6 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58604858; called by muse, mutect2, varscan2
- OR5D18 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV61737788, COSV61738604; called by muse, mutect2, varscan2
- OR5J2 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV56622145; called by muse, mutect2, varscan2
- OR5T1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs371059328, COSV57302248; called by muse, mutect2, varscan2
- OR5T1 | c.920A>T p.K307I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57303546; called by muse, mutect2, varscan2
- OR6N1 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV58649282; called by muse, mutect2, varscan2
- OR9A2 | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63306551; called by muse, mutect2, varscan2
- PALMD | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.355); catalogued as COSV54165387; called by muse, mutect2, varscan2
- PAPPA | c.1846G>A p.G616R | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV60286943; called by muse, mutect2, varscan2
- PCDHA1 | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.396); catalogued as COSV65375249; called by muse, mutect2, varscan2
- PCDHA13 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs1303287274, COSV56493290; called by muse, mutect2, varscan2
- PCDHA13 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.063); catalogued as COSV56494403; called by mutect2, varscan2
- PCDHA9 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.923); catalogued as COSV65328638, COSV65334403; called by muse, mutect2, varscan2
- PCDHB1 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100128208; called by mutect2, varscan2
- PCDHB3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV50573825; called by muse, mutect2, varscan2
- PCNX1 | c.5962C>T p.P1988S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53097173; called by muse, mutect2, varscan2
- PEG3 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV55624470; called by muse, mutect2, varscan2
- PGM5 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs781802650, COSV101124077, COSV67168310; called by muse, mutect2, varscan2
- PIGO | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53054243; called by muse, mutect2, varscan2
- PKDREJ | c.3342G>A p.W1114* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99479009; called by muse, mutect2, varscan2
- PKDREJ | c.3341G>A p.W1114* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99479011; called by muse, mutect2, varscan2
- PLD4 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV66915446; called by muse, mutect2
- PRAMEF7 | c.941G>T p.W314L | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV58278651; called by muse, mutect2, varscan2
- PREB | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV53205518; called by muse, mutect2, varscan2
- PREPL | c.601A>G p.N201D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.317); catalogued as COSV99576230; called by muse, mutect2, varscan2
- PREX2 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55762390; called by muse, mutect2, varscan2
- PRICKLE2 | c.2239C>T p.R747* (on ENST00000295902; = p.R691* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV55768322; called by muse, mutect2, varscan2
- PUM1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57087926; called by muse, mutect2, varscan2
- RAB39B | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as COSV101034998; called by muse, mutect2, varscan2
- RAD52 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57272170, COSV57273390; called by muse, mutect2, varscan2
- RAD54L2 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs200912618, COSV56579726; called by muse, mutect2, varscan2
- RADX | c.1433A>G p.Y478C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs369412417, COSV100998856; called by muse, mutect2, varscan2
- RFX6 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs1309978309, COSV60583429; called by muse, mutect2, varscan2
- RP1 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV55120407; called by muse, mutect2, varscan2
- RTL4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV61206794; called by muse, mutect2, varscan2
- RYR3 | c.5401G>A p.E1801K | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777398893, COSV66778543; called by muse, mutect2, varscan2
- S100A13 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV59884844; called by muse, mutect2, varscan2
- SAMD9 | c.4487G>A p.G1496E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.396); catalogued as COSV66074022; called by muse, mutect2, varscan2
- SDK1 | c.3440G>A p.R1147Q | Missense Mutation (SNP) | VAF 149/293 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67360016, COSV67379281; called by muse, mutect2, varscan2
- SFRP2 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV56837974; called by muse, mutect2, varscan2
- SGMS1 | c.260T>A p.I87N | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV62371176; called by muse, mutect2, varscan2
- SLC22A6 | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV64560474; called by muse, mutect2, varscan2
- SLC4A4 | c.2679G>A p.M893I (on ENST00000264485 / NM_001098484.3; = p.M849I on NM_003759.4) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV52614417, COSV52629125; called by muse, mutect2, varscan2
- SLC8A1 | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs1304648825, COSV60486968, COSV60488977; called by muse, mutect2, varscan2
- SLC8A1 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.178); catalogued as COSV100245574, COSV60486990; called by muse, mutect2, varscan2
- SLC8B1 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.266); catalogued as COSV52529069; called by muse, mutect2, varscan2
- SOX5 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV58636401; called by muse, mutect2, varscan2
- SPEG | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV56673392; called by muse, mutect2, varscan2
- SPEN | c.5222C>T p.S1741L | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs762412019, COSV65364101; called by muse, mutect2, varscan2
- SPESP1 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as COSV99534044; called by muse, mutect2, varscan2
- SPRY3 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100249374, COSV100249663, COSV57143307; called by muse, mutect2, varscan2
- SSTR3 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV60729771; called by muse, mutect2, varscan2
- STAT4 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61830892; called by muse, mutect2, varscan2
- STIL | c.3254C>T p.S1085L | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs190918041, COSV54551569, COSV54554823; called by muse, mutect2, varscan2
- STX19 | c.779A>T p.Y260F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV57399453; called by muse, mutect2, varscan2
- TENM1 | c.3009G>T p.R1003S | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.184); catalogued as COSV64436161; called by muse, varscan2
- TESPA1 | c.988C>T p.L330F (on ENST00000316577 / NM_001098815.3; = p.L192F on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs1172751155, COSV57259774; called by muse, mutect2, varscan2
- TFAM | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65876602; called by muse, mutect2, varscan2
- TGFBRAP1 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.299); catalogued as COSV51513837, COSV51515440; called by muse, varscan2
- TIPARP | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); catalogued as rs373659607, COSV99903869; called by muse, mutect2, varscan2
- TMCO5A | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60465182; called by muse, varscan2
- TMEM175 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV53279747, COSV99297508; called by muse, mutect2, varscan2
- TMEM67 | c.1961-1G>A p.X654_splice | Splice Site (SNP) | VAF 18/62 reads (29%) | catalogued as COSV60041561; called by muse, mutect2, varscan2
- TNFSF10 | c.634A>G p.K212E | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53843711; called by muse, mutect2, varscan2
- TNIP1 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.322); catalogued as rs772854284, COSV59308190; called by muse, mutect2, varscan2
- TPTE | c.1009C>T p.H337Y (on ENST00000618007 / NM_199261.4; = p.H319Y on NM_199259.4) | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302442512; called by muse, mutect2, varscan2
- TRPC7 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.246); catalogued as COSV61452824; called by muse, mutect2, varscan2
- TRPM3 | c.3634G>A p.D1212N (on ENST00000357533 / NM_001366142.2; = p.D1067N on NM_020952.6) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV62589314; called by muse, mutect2, varscan2
- TTN | c.21127G>A p.D7043N (on ENST00000591111; = p.D6116N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | PolyPhen benign (0.189); catalogued as COSV60168503; called by muse, mutect2, varscan2
- TUT4 | c.3364T>C p.Y1122H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57116285; called by muse, mutect2, varscan2
- UGT3A1 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57099898; called by muse, mutect2, varscan2
- UNC5C | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs575164657, COSV71660941; called by muse, mutect2, varscan2
- USP28 | c.2818dup p.V940Gfs*26 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | catalogued as rs1342507221; called by mutect2, pindel, varscan2
- VCAM1 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV54117837; called by muse, mutect2, varscan2
- WIPI2 | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV56589804; called by muse, mutect2, varscan2
- WNT9A | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs537200089, COSV55295658; called by muse, mutect2, varscan2
- ZBED9 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 35/110 reads (32%) | catalogued as COSV71729560; called by muse, mutect2, varscan2
- ZBTB6 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65410306; called by muse, mutect2, varscan2
- ZEB1 | c.2435C>T p.P812L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58048314; called by muse, mutect2, varscan2
- ZMAT1 | c.874A>C p.K292Q | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV65659168; called by muse, mutect2, varscan2
- ZNF287 | c.1571_1573del p.L524del | In Frame Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs768193322; called by pindel, varscan2
- ZNF337 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs762190496, COSV53322108; called by muse, mutect2, varscan2
- ZNF385D | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.792); catalogued as COSV55763069; called by muse, mutect2, varscan2
- ZNF423 | c.3313G>A p.A1105T (on ENST00000563137 / NM_001379286.1; = p.A1097T on NM_015069.4) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV52195660; called by muse, mutect2, varscan2
- ZNF786 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs1191922084, COSV100302800; called by muse, mutect2, varscan2
- ZNF786 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100302803; called by muse, mutect2, varscan2
- COQ8A | c.634_650del p.G212Rfs*69 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
- EIF3H | c.847_867del p.Q283_Q289del | In Frame Del (DEL) | VAF 32/142 reads (23%) | called by mutect2, pindel
- IGHV4-31 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); called by mutect2, varscan2
- MUC13 | c.341_344del p.S114* | Frame Shift Del (DEL) | VAF 49/158 reads (31%) | called by mutect2, pindel, varscan2
- PTPN5 | c.826_828delinsAA p.E276Nfs*34 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by pindel, varscan2*
- RBM5 | c.1719dup p.R574Efs*14 | Frame Shift Ins (INS) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- RBP3 | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMBP3 | c.2635G>A p.G879R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAF1 | c.2780del p.L927Rfs*2 (on ENST00000373790 / NM_138923.4; = p.L948Rfs*2 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 38/91 reads (42%) | called by mutect2, pindel, varscan2
- TRAV12-3 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ABCA2 | c.3156C>T p.S1052= (on ENST00000614293; = p.S1022= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV55803460; called by muse, mutect2, varscan2
- ADAD2 | c.1722G>A p.S574= (on ENST00000315906 / NM_001145400.2; = p.S656= on NM_139174.4) | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs776276942, COSV51892785; called by muse, mutect2, varscan2
- ADGRA1 | c.183C>T p.F61= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as COSV66926204; called by muse, mutect2, varscan2
- ARSF | c.1482C>T p.F494= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as rs746604280, COSV63839955; called by muse, mutect2, varscan2
- ASIC1 | c.702G>A p.G234= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV57318255; called by muse, mutect2, varscan2
- ASIC5 | c.105G>A p.K35= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs762956499, COSV72232952; called by muse, mutect2, varscan2
- ATP7A | c.333G>A p.K111= | Silent (SNP) | VAF 60/366 reads (16%) | catalogued as COSV58448990; called by muse, mutect2, varscan2
- BTBD9 | c.610C>T p.L204= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1363348412, COSV58430261; called by muse, mutect2, varscan2
- BTNL8 | c.150C>T p.A50= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as COSV51458573, COSV51459753; called by muse, mutect2, varscan2
- C12orf60 | c.249G>A p.K83= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV57452504; called by muse, mutect2, varscan2
- C1orf56 | c.672G>A p.G224= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV54847757; called by muse, mutect2, varscan2
- CA14 | c.606C>T p.L202= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV52529823; called by muse, mutect2, varscan2
- CCDC142 | c.234C>T p.P78= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as rs761053024, COSV51778755, COSV99281813; called by muse, mutect2, varscan2
- CCDC33 | c.1515G>A p.R505= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV51501511; called by muse, mutect2, varscan2
- CCDC83 | c.33T>C p.D11= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs1313384556, COSV54703331; called by muse, mutect2, varscan2
- CDH13 | c.1326C>T p.I442= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV51838643; called by muse, mutect2, varscan2
- CENPI | c.732C>T p.F244= | Silent (SNP) | VAF 108/350 reads (31%) | catalogued as COSV54501456, COSV54504070; called by muse, mutect2, varscan2
- COL7A1 | c.5766G>A p.G1922= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV60395803; called by muse, mutect2
- CRB1 | c.3765C>T p.P1255= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs1175098520, COSV66331482; called by muse, mutect2, varscan2
- DCC | c.186C>T p.S62= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs767925738, COSV59084438; called by muse, mutect2, varscan2
- DGAT2L6 | c.231C>T p.T77= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100284021; called by muse, mutect2, varscan2
- DHDDS | c.210C>T p.I70= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as rs1343687682, COSV99360501; ClinVar: likely benign; called by muse, mutect2, varscan2
- DHDDS | c.211C>T p.L71= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as COSV99360502; called by muse, mutect2, varscan2
- DMXL1 | c.7053A>G p.L2351= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV60715554; called by muse, mutect2, varscan2
- DNPEP | c.303C>T p.I101= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs752976790, COSV56111815; called by mutect2, varscan2
- DYNC1LI2 | c.582C>T p.S194= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99263060; called by muse, mutect2, varscan2
- EOLA2 | c.369G>A p.V123= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV62207427; called by muse, mutect2, varscan2
- EPN3 | c.453G>A p.K151= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV52141039; called by muse, mutect2, varscan2
- EVC2 | c.2307C>T p.P769= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs769140131, COSV60396805; called by muse, mutect2, varscan2
- FAT3 | c.477A>C p.S159= | Silent (SNP) | VAF 133/320 reads (42%) | catalogued as COSV53136215; called by muse, varscan2
- FLT3 | c.2808C>T p.F936= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1319450170, COSV99609018; called by muse, mutect2, varscan2
- GAB3 | c.177G>A p.V59= | Silent (SNP) | VAF 40/71 reads (56%) | catalogued as COSV65820074; called by muse, mutect2, varscan2
- GALR1 | c.615C>T p.F205= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV55315806, COSV55317357; called by mutect2, varscan2
- GCK | c.675C>T p.I225= | Silent (SNP) | VAF 160/341 reads (47%) | catalogued as rs772754004, CM012125, COSV60786489; called by muse, mutect2, varscan2
- GMPPA | c.222G>A p.Q74= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV100354670; called by muse, mutect2, varscan2
- IGHV4-31 | c.189G>A p.G63= | Silent (SNP) | VAF 17/149 reads (11%) | called by muse, mutect2, varscan2
- IP6K2 | c.900C>T p.R300= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV53662155; called by muse, mutect2, varscan2
- KCNQ5 | c.633C>T p.I211= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV59653275; called by muse, mutect2, varscan2
- KIF1A | c.831C>T p.T277= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV57486524; called by muse, mutect2, varscan2
- KIR3DL2 | c.1278C>T p.S426= | Silent (SNP) | VAF 90/207 reads (43%) | catalogued as rs374655251, COSV54393578; called by muse, mutect2, varscan2
- LGSN | c.1023G>A p.G341= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV65726548; called by muse, mutect2, varscan2
- LTA | c.405C>T p.V135= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as COSV69304988; called by muse, mutect2, varscan2
- MAP3K2 | c.657A>T p.S219= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100789340; called by muse, mutect2, varscan2
- MAPKAP1 | c.657G>A p.R219= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs778032405, COSV56370401; called by muse, mutect2, varscan2
- MRGPRE | c.345G>A p.A115= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs374090732; called by muse, mutect2, varscan2
- MRGPRX1 | c.873C>T p.L291= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV57106062; called by muse, mutect2, varscan2
- MRM2 | c.168C>T p.S56= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs145102163, COSV54248553; called by muse, mutect2, varscan2
- MS4A2 | c.456G>A p.L152= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV54012983; called by muse, mutect2, varscan2
- MTMR14 | c.1884C>T p.A628= (on ENST00000296003 / NM_001077525.3; = p.A516= on NM_022485.5) | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV56005947; called by muse, mutect2, varscan2
- MUC2 | c.1335G>A p.E445= | Silent (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- MXRA5 | c.4461G>A p.R1487= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV54240805; called by muse, mutect2, varscan2
- MYO9A | c.2622T>C p.I874= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV61853559; called by muse, mutect2, varscan2
- NCAN | c.1956C>T p.T652= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs149325641, COSV53053787; called by muse, mutect2, varscan2
- NEBL | c.2805C>T p.G935= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV65804237; called by muse, mutect2, varscan2
- NEDD4L | c.1734C>T p.D578= (on ENST00000400345 / NM_001144967.3; = p.D558= on NM_015277.6) | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs1173866528, COSV99895171; called by muse, mutect2, varscan2
- NELFB | c.1311G>A p.V437= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV58027053; called by mutect2, varscan2
- NKG7 | c.474C>T p.P158= | Silent (SNP) | VAF 31/174 reads (18%) | catalogued as COSV99389895; called by muse, mutect2, varscan2
- NLRP7 | c.81C>T p.S27= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV60177042; called by muse, mutect2, varscan2
- NSFL1C | c.1095C>T p.I365= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs1294982535, COSV53794088; called by muse, mutect2, varscan2
- NSMCE1 | c.510C>T p.G170= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as rs1037844435, COSV63864486; called by muse, mutect2, varscan2
- NSUN7 | c.1254G>A p.Q418= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs763266426, COSV57274813; called by muse, mutect2, varscan2
- OR10A3 | c.36C>T p.F12= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV62459751; called by mutect2, varscan2
- OR2T33 | c.888G>A p.K296= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV58816180; called by muse, mutect2, varscan2
- OR4K1 | c.627C>T p.S209= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV53460980; called by muse, mutect2, varscan2
- OR51E1 | c.285C>T p.I95= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV67810346; called by mutect2, varscan2
- OR5M11 | c.255C>T p.I85= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs748126869, COSV73141645; called by muse, mutect2, varscan2
- PCDHA13 | c.735C>A p.S245= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV56503496, COSV99166769; called by muse, mutect2, varscan2
- PCDHB10 | c.628T>C p.L210= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as rs1554283993, COSV53381006; called by muse, mutect2, varscan2
- PCDHGA7 | c.2310C>T p.F770= | Silent (SNP) | VAF 46/90 reads (51%) | catalogued as COSV53950889; called by muse, mutect2, varscan2
- PMEPA1 | c.372C>T p.F124= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV55694580; called by mutect2, varscan2
- RAB39B | c.546C>T p.I182= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV65624681, COSV65625397; called by muse, mutect2, varscan2
- RASGRP3 | c.1494G>A p.Q498= (on ENST00000402538 / NM_001349975.2; = p.Q497= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV67822475; called by muse, mutect2, varscan2
- RIMBP3 | c.2634G>A p.E878= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- RRM1 | c.1831C>T p.L611= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV56164946; called by muse, mutect2, varscan2
- SCN10A | c.3486C>T p.I1162= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV71862008; called by muse, mutect2, varscan2
- SCN3A | c.2742G>A p.K914= | Silent (SNP) | VAF 44/139 reads (32%) | catalogued as COSV51815238; called by muse, mutect2, varscan2
- SEC14L1 | c.690C>T p.P230= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as rs138582657; called by muse, mutect2, varscan2
- SEC23B | c.831G>A p.L277= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV52721684; called by muse, mutect2, varscan2
- SPRY3 | c.843C>A p.P281= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV100249376; called by muse, mutect2, varscan2
- TM4SF20 | c.612G>A p.L204= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV58819024; called by muse, mutect2, varscan2
- TMEM211 | c.300G>A p.R100= (on ENST00000423535; = p.R29= on NM_001001663.3) | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs138723870, COSV66954134; called by muse, mutect2, varscan2
- TPM4 | c.81G>A p.A27= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV61209718; called by muse, mutect2, varscan2
- TRPC7 | c.174G>A p.V58= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV100725754, COSV61457696; called by muse, mutect2, varscan2
- TSHB | c.111T>C p.A37= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV56655571; called by muse, mutect2, varscan2
- VIRMA | c.1866G>A p.G622= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV52587292; called by muse, mutect2, varscan2
- WRN | c.1785C>T p.I595= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV53302826, COSV53303640; called by muse, mutect2, varscan2
- XK | c.171C>T p.F57= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV66120425; called by muse, mutect2, varscan2
- ZC3H13 | c.3741A>G p.R1247= | Silent (SNP) | VAF 45/133 reads (34%) | catalogued as COSV54452046, COSV54457638; called by muse, mutect2, varscan2
- ZNF100 | c.1617C>T p.T539= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs759814295, COSV59748577; called by muse, mutect2, varscan2
- ZNF441 | c.1674C>T p.P558= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs745602445, COSV63540179; called by muse, mutect2, varscan2
- ZNF572 | c.1317T>C p.P439= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV60002184; called by muse, mutect2, varscan2
- ZNF621 | c.189C>T p.H63= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV59458432; called by muse, mutect2, varscan2
- ZNF683 | c.660C>T p.L220= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV62874920; called by muse, mutect2, varscan2
- ZNF790 | c.21C>T p.F7= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV63212713; called by muse, mutect2, varscan2
- ZNF888 | c.94C>T p.L32= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as rs754331444, COSV101480808, COSV101480815; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504740 A>G | 5'Flank (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- CDC20B | c.126+1930G>A | Intron (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99696997; called by muse, mutect2, varscan2
- MAGEA5 | n.317G>A | RNA (SNP) | VAF 42/105 reads (40%) | catalogued as rs763665105; called by muse, mutect2, varscan2
- MIR521-1 | n.48G>A | RNA (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- MIR525 | n.36C>T | RNA (SNP) | VAF 14/39 reads (36%) | called by muse, varscan2
- PDPN | c.67+1493G>A | Intron (SNP) | VAF 56/165 reads (34%) | catalogued as COSV99611520; called by muse, mutect2, varscan2
- TECR | c.-68dup | 5'UTR (INS) | VAF 8/24 reads (33%) | called by mutect2, pindel
- THSD4 | c.-80+14331C>T | Intron (SNP) | VAF 13/45 reads (29%) | catalogued as COSV62498842; called by muse, mutect2, varscan2
- TTN | c.10361-4826G>A | Intron (SNP) | VAF 14/41 reads (34%) | catalogued as rs727505032, COSV59951297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWF | c.55+415G>A | Intron (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99779306; called by muse, mutect2, varscan2
